Gene-level copy-number profile of tumor specimen TCGA-39-5035-01A from TCGA case TCGA-39-5035, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.2 years (26,383 days).
Specimen TCGA-39-5035-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e347cb51-7fa2-4621-90a4-889a07d9dd71.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-39-5035-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/697cb6e9-8680-4798-9068-0b1d47a7dd95

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 25; copy number 2: 14,277; copy number 3: 21,124; copy number 4: 15,277; copy number 5: 5,448; copy number 6: 1,593; copy number 7: 227; copy number 8: 996; copy number 9: 60; copy number 10: 80; copy number 11: 226; copy number 13: 245; copy number 14: 50; copy number 15: 38; copy number 17: 92.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-39-5035-01A-01D-1439-01): tumor purity 0.44, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–3,691,814, 51 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1.
- chr9:3,875,584–3,901,248, 2 genes: AL137071.1, GLIS3-AS1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,014 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,344,850–40,423,326, 1 gene, copy number 11 (within-gene range 3–11): SMAP2.
- chr1:40,436,199–48,497,736, 274 genes, copy number 7–11 (broad region; genes not listed).
- chr1:48,552,991–48,776,969, 2 genes, copy number 7 (within-gene range 6–7): AL391844.1, BEND5.
- chr1:58,882,868–59,296,491, 7 genes, copy number 8 (within-gene range 6–8): LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1.
- chr2:19,990,209–20,246,387, 11 genes, copy number 7: AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P.
- chr2:59,778,685–60,439,828, 6 genes, copy number 7: AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432.
- chr3:189,631,389–189,897,276, 1 gene, copy number 8 (within-gene range 6–8): TP63.
- chr3:189,829,922–190,449,876, 9 genes, copy number 8: MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207.
- chr5:58,198–45,895,970, 710 genes, copy number 8–9 (broad region; genes not listed).
- chr9:3,824,127–4,348,392, 1 gene, copy number 17 (within-gene range 0–17): GLIS3.
- chr9:4,070,906–30,832,225, 338 genes, copy number 7–17 (broad region; genes not listed).
- chr19:11,887,782–24,163,425, 654 genes, copy number 8–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
